Gene-level copy-number profile of tumor specimen MP2PRT-PASZKY-TMP1-A from MP2PRT case MP2PRT-PASZKY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,725 days).
Specimen MP2PRT-PASZKY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74523094-c2c2-4a77-91cb-9b50cf776fad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASZKY-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/e91bb09a-7302-49c0-bf6c-54b16864a392

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 2: 15; copy number 3: 109; copy number 4: 39,024; copy number 5: 121; copy number 6: 13,819; copy number 7: 86; copy number 8: 4,867; copy number 9: 293; copy number 10: 21; copy number 11: 5.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,979,352–42,499,134, 12 genes: CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 319 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:20,870,278–22,418,657, 117 genes, copy number 9–10 (broad region; genes not listed).
- chr14:22,455,249–24,576,250, 197 genes, copy number 9–10 (within-gene range 6–12) (broad region; genes not listed).
- chr14:64,914,361–64,944,591, 1 gene, copy number 11 (within-gene range 8–11): CHURC1.
- chr14:64,939,152–64,942,905, 1 gene, copy number 11 (within-gene range 8–11): GPX2.
- chr21:46,635,595–46,691,226, 3 genes, copy number 11: PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
